Somatic mutation profile of tumor specimen 0DJ24Q from CCDI case PBBWFC, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 4.2 years (1,521 days).
Specimen 0DJ24Q: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4603fbe2-c441-4e7b-8730-c26e0115714c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJ24N (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/99bfd5f2-28e0-4bae-8263-a4b1f81002bd

The open-access MAF lists 16 somatic variants for this specimen: 7 protein-altering or splice-affecting, 5 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 5, Intron 2, Nonsense Mutation 1, 5'UTR 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAGEC3 | c.1192G>T p.G398C | Missense Mutation (SNP) | VAF 36/334 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV68924339; called by muse, mutect2, varscan2
- TFDP3 | c.1207G>A p.E403K | Missense Mutation (SNP) | VAF 136/367 reads (37%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0); catalogued as rs765474569; called by muse, mutect2, varscan2
- C1QA | c.602T>C p.V201A | Missense Mutation (SNP) | VAF 42/1324 reads (3%) | SIFT tolerated (0.4); PolyPhen benign (0.185); called by muse, mutect2
- C1orf94 | c.689G>T p.G230V (on ENST00000488417 / NM_001134734.2; = p.G40V on NM_032884.5) | Missense Mutation (SNP) | VAF 21/376 reads (6%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.675); called by muse, mutect2
- CASR | c.2752C>T p.Q918* (on ENST00000490131; = p.Q995* on NM_000388.4) | Nonsense Mutation (SNP) | VAF 229/945 reads (24%) | called by muse, mutect2, varscan2
- FLG | c.11060C>A p.P3687H | Missense Mutation (SNP) | VAF 25/174 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.039); called by mutect2, varscan2
- MUC16 | c.2489A>G p.E830G | Missense Mutation (SNP) | VAF 66/513 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.471); called by muse, mutect2, varscan2
- FBXW12 | c.766T>C p.L256= | Silent (SNP) | VAF 31/1138 reads (3%) | called by muse, mutect2
- FSCN3 | c.1233G>A p.Q411= | Silent (SNP) | VAF 38/1156 reads (3%) | catalogued as rs1328956703, COSV56172109; called by muse, mutect2
- OVOL2 | c.735G>A p.K245= | Silent (SNP) | VAF 271/1223 reads (22%) | called by muse, mutect2, varscan2
- PCDH19 | c.1890C>T p.F630= | Silent (SNP) | VAF 75/761 reads (10%) | catalogued as rs796052791; ClinVar: benign; called by muse, mutect2, varscan2
- WASL | c.1128G>A p.P376= | Silent (SNP) | VAF 111/1514 reads (7%) | catalogued as rs759720155, COSV56136218; called by muse, mutect2
- CALCOCO2 | c.825+76T>A | Intron (SNP) | VAF 16/436 reads (4%) | called by muse, mutect2
- MAP3K9 | c.1690+131A>G | Intron (SNP) | VAF 106/621 reads (17%) | called by muse, mutect2, varscan2
- MPST | c.*19C>T | 3'UTR (SNP) | VAF 43/328 reads (13%) | catalogued as rs1195133309, COSV100353415; called by muse, mutect2, varscan2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 27/252 reads (11%) | called by muse, varscan2
